Surgical pathology report (de-identified scan), TCGA case TCGA-B1-7332, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-7332-01A (Primary Tumor).

AMENDED/CORRECTED REPORT:

Amended date: [REDACTED]

Reason: Spelling / Typographical Edit.

This report being amended is to make correction to a typographical error on diagnostic line 'C' of Part 2, "THE GREATEST DIMENSION OF THE NEOPLASM IS 3.0 cm", which is corrected to read as, "THE GREATEST DIMENSION OF THE NEOPLASM IS 7.5 cm", in the Final Diagnosis field. While it was correctly stated in the Case Synopsis field.

This Amended/Corrected Report reflects NO change to the previously rendered diagnoses.

The attending Physician, [REDACTED] has been notified of the error by e-mail on [REDACTED]

Original sign-out date: [REDACTED]

This Amended Report supersedes all prior reports under this accession number and should be the only one used for patient management. All reports, both original and amended, are maintained in electronic archives and are available upon request.

FINAL DIAGNOSIS:

PART 1: ADIPOSE TISSUE, PERINEPHRIC, EXCISION

- A. UNREMARKABLE FIBROADIPOSE TISSUE.
- B. NO EVIDENCE OF MALIGNANCY.

PART 2: KIDNEY, LEFT, PARTIAL NEPHRECTOMY

- A. PAPILLARY RENAL CELL CARCINOMA, TYPE I.
- B. FUHRMAN NUCLEAR GRADE IS 2.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 7.5 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. THE RENAL VEIN IS NOT INCLUDED IN THIS SPECIMEN AND HAS NOT BEEN EVALUATED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- I. TNM STAGE: pT2a NX MX.

PART 3: KIDNEY, RIGHT, TUMOR BASE, BIOPSY

- A. CAUTERIZED UNREMARKABLE RENAL PARENCHYMA AND ADIPOSE TISSUE
- B. NO EVIDENCE OF MALIGNANCY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Partial nephrectomy
LATERALITY: Left
TUMOR SITE: Not specified
FOCALITY: Unifocal
TUMOR SIZE: Greatest dimension: 7.5 cm
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney
HISTOLOGIC TYPE: Papillary renal cell carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2
PATHOLOGIC STAGING (pTNM): pT2a
pNX
Number of regional lymph nodes examined: 0
pMX
MARGINS: Margins uninvolved by invasive carcinoma
ADRENAL GLAND: Not present
LYMPH-VASCULAR INVASION (LVI): Absent/not identified

PATIENT HISTORY:

No significant history entered
Preop Diagnosis: left renal mass
Postop Diagnosis: left renal mass
Surgical Procedure: NEPHRECTOMY COMPLETE
Reason previous hospitalization/surgery = anterior cervical discectomy
Date of Surgery/Hospitalization = [REDACTED]
Reason previous hospitalization/surgery = lumbar fusion
Date of Surgery/Hospitalization = [REDACTED]
Reason previous hospitalization/surgery = bilateral feet and removal of hardware
Date of Surgery/Hospitalization = [REDACTED]
Reason previous hospitalization/surgery = left rotator cuff repair
Date of Surgery/Hospitalization = [REDACTED]
Reason previous hospitalization/surgery = hyst
Cardiovascular medical history = Atrial fibrillation, Heart murmur, Hypertension
Musculoskeletal medical history = Arthritis, Other: arthritis in neck
Endocrine/metabolic medical history = Diabetes Type II
Gastrointestinal medical history = GERD
Eye/ear medical history = Other: glasses
Genitourinary/renal medical history = Other: mass lt kidney
Skin condition medical history = Piercing
Reaction to anesthesia = No
Reaction to blood/blood products? = Never received blood/blood products

Source: NCI Genomic Data Commons file 10280468-d8ca-40e9-96a4-5e2a7766a407 (TCGA-B1-7332.B6D819B0-AE71-4E39-8E0C-35A7CEE44DC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).